Surgical pathology report (de-identified scan), TCGA case TCGA-QS-A744, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Candler, specimen TCGA-QS-A744-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: _____

ACCT #: _____

LOC: _____

REG DR: _____

AGE/SX: F

ROOM: _____

DOB: _____

BED: _____

STATUS: _____

SPEC #: _____

RECD: _____

STATUS: _____

COLL: _____

TIME IN FORMALIN: _____

hrs.

COLD ISCHEMIA TIME: _____

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis:

Remarks:

- Specimen(s):
- A. Vaginal mass #1 for
- B. Vaginal mass #2 for tumor banking
- C. Right pelvic sidewall
- D. Cul-de-sac
- E. Right uterosacral
- F. Uterus, tubes, ovaries, cervix

MICROSCOPIC DIAGNOSIS

- A. BIOPSY VAGINAL MASS #1:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- B. BIOPSY VAGINAL MASS #2:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- C. BIOPSY RIGHT PELVIC SIDEWALL:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- D. BIOPSY RIGHT CUL-DE-SAC:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- E. BIOPSY RIGHT UTEROSACRAL:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- F. UTERUS, RIGHT AND LEFT OVARIES AND FALLOPIAN TUBES AND UPPER VAGINAL CUFF, DA VINCI ASSISTED RESECTION:
- ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2 OF 3
- TUMOR INVADES MYOMETRIUM TO A DEPTH OF 3 CM IN A MYOMETRIAL WALL OF 3.5 CM THICKNESS
- TUMOR EXTENDS INTO CERVIX AND UPPER VAGINAL CUFF
- SURGICAL MARGINS FREE OF TUMOR
- UTERUS CONTAINS LARGE CALCIFIED LEIOMYOMA
- NO TUMOR SEEN IN BILATERAL OVARIES NOR FALLOPIAN TUBES
- SEE COMMENT FOR SYNOPTIC REPORT

ICD-O-3
Adenocarcinoma, endometrial NOS
8380/3
Site CCF
Isthmus uteri C54.0
path
Endometrium C54.1
8/11/13

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #: PATIENT: (Continued)

COMMENT(S)

Findings are discussed with [REDACTED] by telephone

SURGICAL PATHOLOGY CANCER CASE SUMMARY - APPROVED BY COLLEGE OF AMERICAN PATHOLOGISTS

SPECIMEN: Uterine corpus, cervix, right ovary, left ovary, right fallopian tube, left fallopian tube, left parametrium, right parametrium, vaginal cuff
PROCEDURE: Radical hysterectomy, bilateral salpingo-oophorectomy, peritoneal biopsies
LYMPH NODE SAMPLING: Not performed
SPECIMEN INTEGRITY: Intact hysterectomy specimen
TUMOR SIZE: Greatest dimension: 11 cm
HISTOLOGIC TYPE: Endometrioid adenocarcinoma, not otherwise characterized
HISTOLOGIC GRADE: FIGO grade 2
MYOMETRIAL INVASION: Present
Depth of invasion: 30 mm
Myometrial thickness: 35 mm
INVOLVEMENT OF CERVIX: Invasion of cervical stromal connective tissue
EXTENT OF INVOLVEMENT OF OTHER ORGANS: Right ovary: not involved
Left ovary: not involved
Right fallopian tube: not involved
Left fallopian tube: not involved
Vagina: involved
LYMPH-VASCULAR INVASION: Present
PATHOLOGIC STAGING: Primary tumor: pT3b (IIIB)
Regional lymph nodes: pNX
No nodes submitted or found
Distant metastasis: not applicable

GROSS DESCRIPTION:

The specimen is received in multiple parts.

A. This specimen in the fresh state for immediate gross evaluation is fragments of soft, pink tumor measuring 3 x 1 x 1 cm. A representative fragment is removed by aseptic technique and submitted to [REDACTED] according to their protocol. Representative sections are submitted as blocks A1-A3.

B. This is fragments of pink tumor which in aggregate measure 4 x 3 x 2 cm. A representative portion is removed by aseptic technique and submitted for tumor banking. Representative sections are submitted as blocks B1-B3.

C. This is one 3 mm fragment of pink tissue, totally submitted as block C1.

D. This is one 8 mm fragment of pink tissue, totally submitted as block D1.

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #:

(Continued)

GROSS DESCRIPTION: (Continued)

E. This is 1 mL of hemorrhagic material without grossly recognizable tissue fragments, totally submitted as block E1.

F. This specimen is brought by _____ to the laboratory for immediate gross evaluation. The specimen is dissected and reviewed with _____ and consists of a uterus and cervix with attached bilateral ovaries and fallopian tubes. The right fallopian tube appears unremarkable and measures 8 x 0.4 cm. The right ovary is wrinkled and tan and measures 3 x 1.5 x 1.5 cm. The left fallopian tube is unremarkable and measures 8 x 0.5 cm. The left ovary is wrinkled and tan and measures 3.5 x 2 x 1.5 cm. The uterus weighs 579 grams and with the cervix measures 12 x 9 x 11 cm. Much of the weight and volume of the uterus consists of a densely calcified leiomyoma which measures 7 cm. The cervix measures 4 x 4 x 4 cm and is completely replaced by irregular, firm, tan and red tumor. Likewise, the endometrial cavity and myometrium are subtotally replaced by an invasive, tan tumor which in the fundus measures 8.5 x 6 x 6 cm. Maximum depth of myometrial invasion is 3 cm with a myometrial wall thickness of 3.5 cm. A vaginal cuff margin of 0.5 cm surrounds the tumor in the cervix. I have applied blue ink to the deep paracervical margins. The following sections are submitted:

- Block F1 - right tube and ovary
- Block F2 - left tube and ovary
- Blocks F3, F4 - posterior vaginal cuff, blue ink on deep margin
- Blocks F5, F6 - anterior vaginal cuff, blue ink on deep margin
- Block F7 - endocervix with tumor
- Block F8-F12 - endomyometrium
- Block F13 - leiomyoma
- Block F14 - uterine serosa

The uterine cavity measures 7 x 4.5 x 0.5 cm. The uterine serosa is intact and not penetrated by tumor.

INTRAOPERATIVE CONSULTATION:

A. IMMEDIATE GROSS EVALUATION, VAGINAL MASS #1:

- MALIGNANT TUMOR, PROCESSED FOR

ANALYSIS

B. IMMEDIATE GROSS EVALUATION, VAGINAL MASS #2:

- MALIGNANT TUMOR, PROCESSED FOR TUMOR BANKING

F. IMMEDIATE GROSS EVALUATION, UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES:

- EXTENSIVE MALIGNANT TUMOR CONSISTENT WITH CARCINOMA OF ENDOMETRIAL ORIGIN

PHOTO DOCUMENTATION

Image Picture Copy Error
Image Picture Copy Error
Image Picture Copy Error

Signed _____ (signature on file) _____

** END OF REPORT **

Reviewed (Initials) _____	Date Reviewed: 8/1/13	

Source: NCI Genomic Data Commons file 0d6e7c50-a122-4e30-a536-23a085472d98 (TCGA-QS-A744.F37C9C5C-8AAA-47FB-8BAD-AE2EB0F70B4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).